Gene-level copy-number profile of tumor specimen BLGSP-71-08-00194-01A from CGCI case BLGSP-71-08-00194, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.8 years (2,831 days).
Specimen BLGSP-71-08-00194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Mesentery; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8bf1c979-6a21-4990-9c35-a5c547fdd7d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00194-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/c1b596b5-3833-4c35-94ed-27ea3904adef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 71; copy number 2: 58,079; copy number 3: 239.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
